Gene-level copy-number profile of tumor specimen TCGA-BF-A5EP-01A from TCGA case TCGA-BF-A5EP, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 75.6 years (27,622 days).
Specimen TCGA-BF-A5EP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.279e6cf6-1bac-49f3-bcd7-7fa370ca1de6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BF-A5EP-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c3b09955-5fc8-4501-a681-04962d359526

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 33; copy number 1: 32; copy number 2: 20,381; copy number 3: 9,549; copy number 4: 26,841; copy number 5: 525; copy number 6: 2,252; copy number 8: 73; copy number 10: 127.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BF-A5EP-01A-12D-A27J-01): tumor purity 0.75, ploidy 3.21, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 33 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:107,985,089–108,974,476, 33 genes (within-gene range 0–2): AL024507.1, SNORA73, MTHFD2P3, RPL3P7, Z98200.1, OSTM1, Y_RNA, OSTM1-AS1, NR2E1, AL078596.1, SNX3, Z98742.2, RNA5SP212, Z98742.4, Z98742.1, RNU6-1144P, AFG1L, Z98742.3, AL356121.2, AL356121.1, AL353706.1, RNU6-770P, AL139106.1, AL391646.1, FOXO3, SUMO2P8, LINC00222, ZNF259P1, Z95118.2, Z95118.1, ARMC2, AL445189.1, ATP5MFP2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 127 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:64,045,429–66,995,587, 127 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 32. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
